Surgical pathology report (de-identified scan), TCGA case TCGA-Z2-AA3V, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site IDI-IRCCS, specimen TCGA-Z2-AA3V-06A (Metastatic).

ICD-O-3
Melanoma NOS 8720/3
Site: Lymph node Papilla
0773
JW 1/12/14

Histology number:

Sex: F

Age:

Lesion site: Right axillary

Macroscopy: 12x7x3 cm fragment of adipose tissue containing lymph nodes. The biggest lymph node has a maximum diameter of 3 cm and a blackish color. Included representative sections

Microscopy:

Diagnosis: Melanoma metastasis in 9 out of 27 lymph nodes examined. pN3 according to UICC 2009

Proposed by:

Biopsy by:

Division:

Date of Biopsy:

Accepted:

Pathology Report Date:

Pathology Report:

Source: NCI Genomic Data Commons file ce01ae19-eaaf-4ae6-811a-994d7a4b3b87 (TCGA-Z2-AA3V.170DD4A4-10A3-4600-99F5-FF5C81F09157.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).